Somatic mutation profile of tumor specimen HCM-CSHL-0187-C25-01A (aliquot HCM-CSHL-0187-C25-01A-11D-A78L-36) from HCMI case HCM-CSHL-0187-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 67.2 years (24,541 days).
Specimen HCM-CSHL-0187-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c339bb42-4650-466f-a745-7efc83483e53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0187-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0187-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c49f961d-3f49-4532-95bd-5e828f363a34

The open-access MAF lists 45 somatic variants for this specimen: 27 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 13, Intron 5, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 74/318 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 170/491 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDON | c.1894C>T p.R632* | Nonsense Mutation (SNP) | VAF 133/539 reads (25%) | catalogued as rs752726620, COSV54997436; called by muse, mutect2, varscan2
- CSMD3 | c.5873C>A p.P1958H (on ENST00000297405 / NM_001363185.1; = p.P1854H on NM_052900.3) | Missense Mutation (SNP) | VAF 38/794 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52188668; called by muse, mutect2
- DTX1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1174280354; called by muse, mutect2, varscan2
- FLNB | c.7166C>T p.A2389V | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs541479906; called by muse, mutect2, varscan2
- HHLA1 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 116/884 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs192941170; called by muse, mutect2, varscan2
- HSPA12A | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs781927735, COSV65023418; called by muse, mutect2, varscan2
- OR5AS1 | c.248C>A p.A83E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs1323955707; called by muse, mutect2, varscan2
- OR5M11 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs544158488, COSV73141926; called by muse, mutect2, varscan2
- OR8A1 | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV52509668; called by muse, mutect2, varscan2
- SEZ6 | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs996119903; called by muse, mutect2
- TRANK1 | c.4790C>T p.T1597I | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1471447054; called by muse, mutect2, varscan2
- TTN | c.56773G>A p.V18925I (on ENST00000591111; = p.V11501I on NM_003319.4) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | PolyPhen probably damaging (0.991); catalogued as rs764777213; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- ATP8A2 | c.3052T>G p.L1018V | Missense Mutation (SNP) | VAF 66/263 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- CCNP | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCZ1B | c.272dup p.F92Vfs*4 | Frame Shift Ins (INS) | VAF 24/180 reads (13%) | called by mutect2, varscan2
- CUL4B | c.1688T>C p.I563T | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FMN1 | c.226A>C p.K76Q | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- GABRB3 | c.484A>C p.M162L | Missense Mutation (SNP) | VAF 227/505 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- GSDME | c.326T>A p.V109E | Missense Mutation (SNP) | VAF 72/330 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- LAMA3 | c.2245G>A p.D749N | Missense Mutation (SNP) | VAF 209/548 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- NCOA2 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PDZRN3 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- PLEKHG7 | c.1625T>A p.L542* | Nonsense Mutation (SNP) | VAF 50/195 reads (26%) | called by muse, mutect2, varscan2
- SMAD3 | c.1259_*7del | Nonstop Mutation (DEL) | VAF 103/267 reads (39%) | called by mutect2, pindel, varscan2
- TDRD15 | c.216_217del p.S73Wfs*14 | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | called by mutect2, pindel, varscan2
- ABCC11 | c.3498C>T p.R1166= | Silent (SNP) | VAF 41/169 reads (24%) | catalogued as rs770735735; called by muse, mutect2, varscan2
- AJM1 | c.225C>T p.S75= | Silent (SNP) | VAF 83/381 reads (22%) | called by muse, mutect2, varscan2
- IKBKE | c.729T>A p.A243= | Silent (SNP) | VAF 35/149 reads (23%) | called by muse, mutect2, varscan2
- ITIH2 | c.2493T>C p.V831= | Silent (SNP) | VAF 26/169 reads (15%) | called by muse, mutect2, varscan2
- MOSPD2 | c.258C>T p.P86= | Silent (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- MYH9 | c.5532G>A p.L1844= | Silent (SNP) | VAF 127/542 reads (23%) | catalogued as rs774510520, COSV53385198; called by muse, mutect2, varscan2
- NTN4 | c.150C>T p.D50= | Silent (SNP) | VAF 61/306 reads (20%) | called by muse, mutect2, varscan2
- PEG3 | c.3264C>G p.V1088= | Silent (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- RBMXL2 | c.261G>A p.P87= | Silent (SNP) | VAF 96/366 reads (26%) | catalogued as rs780712714, COSV60981228; called by muse, mutect2, varscan2
- ROBO2 | c.3669C>T p.D1223= | Silent (SNP) | VAF 63/304 reads (21%) | catalogued as rs2272164, COSV59901154; called by muse, mutect2, varscan2
- TRIM64C | c.165C>T p.C55= | Silent (SNP) | VAF 125/552 reads (23%) | catalogued as COSV73267185; called by muse, mutect2, varscan2
- TUBB4A | c.1056C>T p.A352= | Silent (SNP) | VAF 145/617 reads (24%) | catalogued as rs140196381; called by muse, mutect2, varscan2
- ZNF587B | c.465G>A p.A155= | Silent (SNP) | VAF 117/482 reads (24%) | catalogued as rs749342872, COSV100331908; called by muse, mutect2, varscan2
- ASH1L | c.5828+4339C>T | Intron (SNP) | VAF 119/548 reads (22%) | catalogued as rs756725717; called by muse, mutect2, varscan2
- IL7R | c.801-73G>C | Intron (SNP) | VAF 69/336 reads (21%) | called by muse, mutect2, varscan2
- MYO18A | c.1000-11547A>G | Intron (SNP) | VAF 45/306 reads (15%) | called by muse, mutect2, varscan2
- NKX6-3 | c.553-585C>T | Intron (SNP) | VAF 85/224 reads (38%) | catalogued as rs575445619, COSV72895081; called by muse, mutect2, varscan2
- ZNF720 | c.361+1525C>A | Intron (SNP) | VAF 26/109 reads (24%) | called by muse, mutect2, varscan2
